Somatic mutation profile of tumor specimen TCGA-RR-A6KC-01A (aliquot TCGA-RR-A6KC-01A-31D-A33T-08) from TCGA case TCGA-RR-A6KC, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 55.6 years (20,302 days).
Specimen TCGA-RR-A6KC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 046a4b80-1b58-4b34-b70f-70574ca4ebf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RR-A6KC-10A (Blood Derived Normal), aliquot TCGA-RR-A6KC-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8d68fb9-a686-4af0-8d70-2087458e4596

The open-access MAF lists 50 somatic variants for this specimen: 34 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 15, Nonsense Mutation 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 337/830 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV51767495, COSV51850592; called by muse, mutect2, varscan2
- PIK3CA | c.1133G>T p.C378F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as CM126691, COSV55930877, COSV55952006; called by muse, mutect2, varscan2
- ABCB5 | c.2842C>T p.R948* (on ENST00000404938 / NM_001163941.2; = p.R503* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as rs1158560751, COSV51705757; called by muse, mutect2, varscan2
- ABCC3 | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576176010, COSV53322872; called by muse, mutect2, varscan2
- BAZ1A | c.3449G>A p.R1150H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1566547758, COSV62411128; called by muse, mutect2, varscan2
- CCDC60 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV100554596, COSV59547181; called by muse, mutect2, varscan2
- CDH9 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99141482; called by muse, mutect2, varscan2
- CNTN1 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs142561108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREB3 | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100147262; called by muse, mutect2, varscan2
- CRYGN | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs536032923, COSV100484685; called by muse, mutect2, varscan2
- ENTPD8 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs757572891, COSV100395441; called by muse, mutect2, varscan2
- HPS5 | c.3014A>G p.N1005S (on ENST00000349215 / NM_181507.2; = p.N891S on NM_007216.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.591); catalogued as rs773572686, COSV61687141; called by muse, mutect2, varscan2
- IRS2 | c.3996G>T p.E1332D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.351); catalogued as COSV101018797; called by muse, mutect2, varscan2
- KLHDC8A | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV100903782; called by muse, mutect2, varscan2
- KRT34 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs143564749; called by muse, mutect2, varscan2
- LILRA2 | c.1034A>C p.Q345P | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99252694; called by muse, mutect2, varscan2
- LILRA2 | c.1390G>A p.G464R (on ENST00000391738 / NM_001130917.3; = p.G447R on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs754197619, COSV52196427; called by muse, mutect2
- LRRC23 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as COSV99145120; called by muse, mutect2, varscan2
- LRRIQ1 | c.3176C>A p.P1059H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101279468; called by muse, mutect2, varscan2
- MATK | c.509G>A p.R170H (on ENST00000310132 / NM_139355.3; = p.R171H on NM_002378.4) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1328101549, COSV100035826; called by muse, mutect2, varscan2
- MAU2 | c.1462A>G p.M488V | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.469); catalogued as COSV99448252; called by muse, mutect2, varscan2
- MYLK3 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs767498123, COSV101189139, COSV67363934; called by muse, mutect2, varscan2
- N4BP2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs780476202, COSV54699826; called by muse, mutect2, varscan2
- NLRP9 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 60/195 reads (31%) | catalogued as rs758128073, COSV60463249; called by muse, mutect2, varscan2
- OR1Q1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as rs756129489, COSV52917127; called by muse, mutect2, varscan2
- OR2W3 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs750858075, COSV64455944, COSV64458463; called by muse, mutect2, varscan2
- OR51G1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs143904984, COSV58970464; called by muse, mutect2, varscan2
- OR5J2 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs760964840, COSV56620223, COSV56620652; called by muse, mutect2, varscan2
- PRPF8 | c.5144A>G p.Y1715C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100517115; called by muse, mutect2, varscan2
- PTCHD4 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); catalogued as rs370719620; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1157A>G p.H386R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV99424404; called by muse, mutect2, varscan2
- USP53 | c.1448A>C p.E483A | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV99917495; called by muse, mutect2, varscan2
- WDR47 | c.2650G>A p.V884M (on ENST00000369962 / NM_001142551.2; = p.V885M on NM_014969.5) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100728228; called by muse, mutect2, varscan2
- TRPM7 | c.2716_2717del p.M906Vfs*2 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- AP2B1 | c.1839G>A p.T613= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs753931704, COSV99250836; called by muse, mutect2, varscan2
- DOK5 | c.699G>A p.Q233= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99373220; called by muse, mutect2, varscan2
- EPHA8 | c.2457C>T p.S819= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as rs765282827, COSV51262345; called by muse, mutect2, varscan2
- IGLV3-9 | c.264G>A p.T88= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs368822621; called by muse, mutect2, varscan2
- IL1R1 | c.411C>T p.D137= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs767046307, COSV99292350; called by muse, mutect2, varscan2
- INPP5D | c.1269G>A p.T423= (on ENST00000445964 / NM_001017915.3; = p.T422= on NM_005541.5) | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as rs377021577, COSV100856504; called by muse, mutect2, varscan2
- ITPR2 | c.1287C>T p.F429= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs372220989; called by muse, mutect2, varscan2
- LATS2 | c.2517C>T p.S839= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs771575305, COSV101231461; called by muse, mutect2, varscan2
- PCDHA5 | c.1284C>T p.D428= | Silent (SNP) | VAF 72/155 reads (46%) | catalogued as rs782621396, COSV65356090; called by muse, mutect2, varscan2
- PHKB | c.1680C>T p.L560= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs1162948454, COSV54532903; called by muse, mutect2, varscan2
- PNKD | c.507G>A p.L169= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV99282151; called by muse, mutect2, varscan2
- RRM1 | c.612T>G p.T204= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100331214; called by muse, mutect2, varscan2
- SLC24A3 | c.666G>T p.L222= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV60123410; called by muse, mutect2
- TSPY1 | c.342C>G p.A114= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs756779239, COSV101369641; called by mutect2, varscan2
- ZFP91 | c.1110G>A p.R370= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100284304; called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630539 G>T | 5'Flank (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
